Surgical pathology report (de-identified scan), TCGA case TCGA-Q1-A6DW, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site University of Oklahoma HSC, specimen TCGA-Q1-A6DW-01A (Primary Tumor).

[page 1 of 2]
RUN DATE:
RUN TIME:
BY:

LABORATORY
Specimen Inquiry

PAGE:1

SPEC #:
STATUS:

Obtained:
Received:

Subm Dr:

CLINICAL HISTORY:
ICD-180.9

SPECIMEN/PROCEDURE:
1. CERVICAL BIOPSY

*ICD 0-3
Carcinoma, squamous cell,
large cell non keratinizing 8072/3
Site Cervix NOS C53.9
6/3/13*

IMPRESSION:

CERVIX, BIOPSY:

- . Invasive squamous cell carcinoma, large cell nonkeratinizing type, moderately differentiated.
- . Extensive severe dysplasia.

Dictated by:
Entered:

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and cervical biopsy. Received are 3 pale pink to gray tan slightly hemorrhagic tissue fragments ranging from 0.4-1.4 cm in greatest dimension. The larger fragment be trisected perpendicular to the long axis. The specimen is entirely submitted in cassette 1A.

Dictated by:
Entered:

COPIES TO:

Does Not Know

CPT Codes:

CERVICAL BIOPSY/88305

ICD9 Codes:

180.9

Resident Physician:

I have personally reviewed the material
(specimen/slide) and approve this final report.

** CONTINUED ON NEXT PAGE **

[page 2 of 2]
Electronically Signed by: _____

Physicians

** END OF REPORT **

IIA Discrepancy		☒

Source: NCI Genomic Data Commons file 93baf831-a78e-4d3d-9bf2-f9c6e47cd2b1 (TCGA-Q1-A6DW.5C7158E0-E120-4D7C-A68D-FA3853507A83.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).